Gene-level copy-number profile of tumor specimen TCGA-24-2289-01A from TCGA case TCGA-24-2289, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.0 years (25,191 days).
Specimen TCGA-24-2289-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2805596c-3015-489a-8683-8df919934cb8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2289-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac066ee9-8a66-4906-854a-3cf68f602e4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 7,788; copy number 2: 27,644; copy number 3: 14,481; copy number 4: 6,184; copy number 5: 2,357; copy number 6: 644; copy number 7: 98; copy number 8: 379; copy number 9: 36; copy number 10: 79; copy number 13: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2289-01A-01D-0704-01): tumor purity 0.61, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,373,353–3,700,628, 3 genes: AC026991.1, AC026991.2, RNA5SP251.
- chr9:99,979,185–100,099,000, 1 gene (within-gene range 0–1): ERP44.
- chr9:100,099,243–100,302,175, 5 genes (within-gene range 0–1): INVS, RN7SL75P, RPS2P35, AL137072.1, NANOGP5.
- chr15:73,443,164–73,634,134, 4 genes (within-gene range 0–3): REC114, MRPS15P1, NPTN, NPTN-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,692 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–19,485,539, 634 genes, copy number 5 (broad region; genes not listed).
- chr1:19,510,593–19,510,733, 1 gene, copy number 5: RNU4-28P.
- chr1:74,963,314–76,779,267, 27 genes, copy number 5: AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1, AC092813.2, ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567.
- chr1:97,077,743–105,893,517, 106 genes, copy number 7–9 (broad region; genes not listed).
- chr1:109,603,254–110,631,474, 44 genes, copy number 6 (within-gene range 4–6): GNAT2, AMPD2, AL355310.2, RPL7P8, GSTM4, GSTM2, GSTM1, AC000032.1, GSTM5, AL158847.1, GSTM3, EPS8L3, NDUFA5P10, LINC01768, AL450468.1, AL450468.2, CSF1, AHCYL1, STRIP1, AL160006.1, ALX3, LINC01397, UBL4B, SLC6A17, SLC6A17-AS1, AL355990.1, LINC02586, KCNC4, AL137790.2, AL137790.1, RBM15-AS1, RBM15, LAMTOR5-AS1, SLC16A4, AL355488.1, LAMTOR5, PROK1, AL358215.1, AL358215.2, AL358215.3, CYMP, CYMP-AS1, KCNA10, KCNA2.
- chr1:232,221,938–232,223,145, 2 genes, copy number 5: BX323014.1, RN7SL299P.
- chr2:22,861,552–42,493,982, 361 genes, copy number 5 (broad region; genes not listed).
- chr2:42,511,570–42,533,442, 2 genes, copy number 5: Metazoa_SRP, AC025750.1.
- chr2:45,569,199–46,501,278, 15 genes, copy number 7: RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247.
- chr3:175,773,145–176,867,838, 8 genes, copy number 5 (within-gene range 3–5): NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977.
- chr4:15,960,245–20,620,561, 43 genes, copy number 5–6: FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63, AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1.
- chr4:146,706,638–147,684,163, 16 genes, copy number 6 (within-gene range 3–6): TTC29, AC092435.2, AC092435.1, AC092435.3, AC092435.4, AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9.
- chr4:147,745,303–147,809,209, 3 genes, copy number 6: RNA5SP165, MIR4799, RN7SL254P.
- chr4:160,539,254–164,384,050, 25 genes, copy number 5 (within-gene range 4–5): LINC02477, RPS14P7, AC104793.1, FSTL5, AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16, MARCHF1, AC093788.1, RN7SKP105, YWHAQP4, AC105250.1, ANP32C.
- chr5:164,296,696–165,171,643, 1 gene, copy number 5 (within-gene range 4–5): AC109466.1.
- chr5:164,935,162–174,006,140, 135 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–11,709,960, 231 genes, copy number 5 (broad region; genes not listed).
- chr6:127,118,671–127,288,567, 2 genes, copy number 5 (within-gene range 3–5): RSPO3, RNF146.
- chr7:22,725,884–23,491,893, 25 genes, copy number 5 (within-gene range 4–5): IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA.
- chr7:26,637,871–29,514,667, 79 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:127,652,194–132,087,992, 139 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr7:133,082,829–134,066,589, 7 genes, copy number 5: RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27.
- chr8:86,553,977–87,615,219, 8 genes, copy number 5 (within-gene range 4–5): CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:101,261,541–145,066,685, 669 genes, copy number 6–10 (broad region; genes not listed).
- chr11:74,000,277–87,021,909, 250 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:113,265,137–118,897,787, 148 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:2,603,350–9,128,645, 272 genes, copy number 6 (broad region; genes not listed).
- chr14:90,396,502–91,575,271, 27 genes, copy number 5: CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2, AL122020.1, LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3.
- chr15:23,140,563–25,420,336, 130 genes, copy number 6–13 (within-gene range 2–13) (broad region; genes not listed).
- chr15:51,037,488–51,293,912, 1 gene, copy number 6 (within-gene range 3–6): MIR4713HG.
- chr15:51,208,057–52,295,804, 43 genes, copy number 6: CYP19A1, MIR4713, AC020891.3, MIR7973-2, MIR7973-1, AC020891.2, GLDN, AC020891.4, AC020891.1, AC066613.2, DMXL2, AC066613.1, SCG3, AC020892.1, AC020892.2, LYSMD2, TMOD2, AC026770.1, TMOD3, AC090971.5, Metazoa_SRP, AC090971.4, Y_RNA, AC090971.2, RNU6-90P, AC090971.1, AC090971.3, LEO1, MAPK6, MAPK6-DT, AC090970.2, AC090970.1, AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266.
- chr15:60,004,234–60,223,272, 4 genes, copy number 6: FOXB1, MESTP2, AC009654.1, AC037433.1.
- chr15:82,647,770–87,047,303, 120 genes, copy number 5 (broad region; genes not listed).
- chr18:23,134,564–24,708,542, 40 genes, copy number 5: CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57.
- chr18:31,829,197–35,406,528, 59 genes, copy number 5–6: TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4.
- chr21:46,229,196–46,665,124, 15 genes, copy number 5 (within-gene range 2–5): MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 7,464. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
